Somatic mutation profile of tumor specimen TCGA-IB-7647-01A (aliquot TCGA-IB-7647-01A-11D-2154-08) from TCGA case TCGA-IB-7647, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 41.6 years (15,188 days).
Specimen TCGA-IB-7647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f231df97-1fdf-437b-876e-cbc528bc8223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7647-10A (Blood Derived Normal), aliquot TCGA-IB-7647-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9890e9e0-53e4-44fb-90b7-c63a19f7eedf

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, RNA 2, Nonsense Mutation 2, Frame Shift Ins 2, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 43/278 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTA1 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100796696; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2788G>A p.G930S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs763669513, COSV65891345; called by muse, mutect2, varscan2
- ADCY8 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV53920279; called by muse, mutect2
- ADGRG4 | c.6232G>C p.G2078R | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV99794240; called by muse, mutect2
- ANK3 | c.3455G>C p.G1152A (on ENST00000280772 / NM_001320874.2; = p.G286A on NM_001149.3) | Missense Mutation (SNP) | VAF 72/597 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55045770, COSV99778098; called by muse, mutect2, varscan2
- CELSR3 | c.9349C>T p.R3117W | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs1352394379, COSV51072996; called by muse, mutect2, varscan2
- CEP44 | c.281dup p.Q95Afs*17 | Frame Shift Ins (INS) | VAF 31/273 reads (11%) | catalogued as rs1407057449; called by mutect2, pindel, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2
- DDX31 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 90/794 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs367667543; called by muse, mutect2, varscan2
- FPGS | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 63/638 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100785202; called by muse, mutect2, varscan2
- GDE1 | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 72/690 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100783137; called by muse, mutect2, varscan2
- GFUS | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 94/619 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV71254366; called by muse, mutect2, varscan2
- IGSF10 | c.7024C>G p.P2342A | Missense Mutation (SNP) | VAF 32/948 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1436022185, COSV99176580, COSV99193374; called by muse, mutect2
- LRFN5 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99982396; called by muse, mutect2, varscan2
- LRRC4C | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 31/623 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767978305, COSV53417350, COSV99536828; called by muse, mutect2
- LRRCC1 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 88/705 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100835264; called by muse, mutect2, varscan2
- LUC7L3 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1262728141, COSV99536697; called by muse, mutect2, varscan2
- MUC16 | c.13445C>T p.A4482V | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377647571; called by muse, mutect2
- NELL2 | c.1929T>A p.D643E | Missense Mutation (SNP) | VAF 89/853 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100418590; called by muse, mutect2, varscan2
- NFATC2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 23/455 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101043533, COSV101044967; called by muse, mutect2
- NLRC5 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1361850600, COSV99346381; called by muse, mutect2
- NOTCH3 | c.6932C>T p.P2311L | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs771682246, COSV99655690; called by muse, mutect2, varscan2
- OR2L13 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 30/800 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100813653; called by muse, mutect2
- OTOF | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.635); catalogued as rs754009907, COSV99716396; ClinVar: uncertain significance; called by muse, mutect2
- PIK3CA | c.2935A>G p.R979G | Missense Mutation (SNP) | VAF 62/504 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.468); catalogued as COSV99833306; called by muse, mutect2, varscan2
- RYR1 | c.5227G>A p.A1743T | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs1392565021, COSV100614289; called by muse, mutect2, varscan2
- SEC31B | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs376511713; called by muse, mutect2, varscan2
- SLC37A1 | c.1524C>T p.F508= | Splice Region (SNP) | VAF 19/177 reads (11%) | catalogued as rs1223367874, COSV100721542; called by muse, mutect2, varscan2
- TBX5 | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100090386; called by muse, mutect2, varscan2
- TCF7L1 | c.1144A>T p.R382* | Nonsense Mutation (SNP) | VAF 12/308 reads (4%) | catalogued as COSV99964130; called by muse, mutect2
- TMCC2 | c.1942A>G p.N648D | Missense Mutation (SNP) | VAF 73/623 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1307902103, COSV100319137; called by muse, mutect2, varscan2
- TTN | c.51389G>T p.G17130V (on ENST00000591111; = p.G9706V on NM_003319.4) | Missense Mutation (SNP) | VAF 86/1676 reads (5%) | PolyPhen probably damaging (1); catalogued as COSV100592544; called by muse, mutect2
- TUBA1A | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 41/1106 reads (4%) | catalogued as rs1237540680; called by muse, mutect2
- UQCRC2 | c.514+1G>T p.X172_splice | Splice Site (SNP) | VAF 34/339 reads (10%) | catalogued as COSV104390998, COSV99193263; called by muse, mutect2, varscan2
- ZNF671 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 35/634 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV58054648; called by muse, mutect2
- ZNF777 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 95/719 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.052); catalogued as rs552895043, COSV99924960; called by muse, mutect2, varscan2
- EXOSC8 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 20/588 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2
- RREB1 | c.956_959dup p.C321Hfs*3 | Frame Shift Ins (INS) | VAF 20/166 reads (12%) | called by mutect2, pindel
- ADH1A | c.337T>C p.L113= | Silent (SNP) | VAF 55/370 reads (15%) | catalogued as COSV99265632; called by muse, mutect2, varscan2
- GDE1 | c.402T>A p.I134= | Silent (SNP) | VAF 76/717 reads (11%) | catalogued as COSV100783136; called by muse, mutect2
- GPR45 | c.75G>A p.G25= | Silent (SNP) | VAF 26/466 reads (6%) | catalogued as COSV99306621; called by muse, mutect2
- MAGEB16 | c.45C>T p.H15= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs928586346, COSV101303269, COSV67874136; called by muse, mutect2, varscan2
- NKX2-2 | c.504G>A p.T168= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as rs925867289, COSV101010477, COSV101010516; called by muse, mutect2, varscan2
- OR11H1 | c.123G>A p.L41= | Silent (SNP) | VAF 58/1600 reads (4%) | catalogued as COSV99421545; called by muse, mutect2
- PCDHA2 | c.1812C>T p.N604= | Silent (SNP) | VAF 29/445 reads (7%) | catalogued as rs1554120103, COSV65366812; called by muse, mutect2
- RTN4RL1 | c.126G>A p.A42= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs200721283, COSV100486404; called by muse, mutect2, varscan2
- TSSK6 | c.579C>T p.Y193= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as rs747464688, COSV99388891; called by muse, mutect2, varscan2
- TTN | c.5085T>C p.Y1695= (on ENST00000591111; = p.Y1649= on NM_003319.4) | Silent (SNP) | VAF 57/410 reads (14%) | catalogued as rs1235228503, COSV100592550; called by muse, mutect2, varscan2
- OR2W5 | n.1081C>T | RNA (SNP) | VAF 26/671 reads (4%) | catalogued as rs1191921872; called by muse, mutect2
- PGAP2 | c.165+5934G>A | Intron (SNP) | VAF 61/537 reads (11%) | catalogued as rs575675293, COSV53465455; called by muse, mutect2, varscan2
- SNORD109A | n.61G>A | RNA (SNP) | VAF 12/201 reads (6%) | called by muse, mutect2
